Gene-level copy-number profile of tumor specimen TCGA-DW-7840-01A from TCGA case TCGA-DW-7840, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 60.6 years (22,141 days).
Specimen TCGA-DW-7840-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.5d96734f-08ec-4041-b372-1b01d2bece22.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DW-7840-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/424cce00-df0b-4d98-bcf0-74bc0d3c4304

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,660; copy number 2: 47,049; copy number 3: 6,097; copy number 4: 91; copy number 5: 2,923.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DW-7840-01A-11D-2135-01): tumor purity 0.85, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,923 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–73,842,516, 1,367 genes, copy number 5 (broad region; genes not listed).
- chr7:76,902,480–159,233,377, 1,556 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
